CPTAC case C3N-00660 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e28cc014-3361-4776-9e90-389dff7441fd

Demographics
Sex at birth: female; Race: white; Year of birth: 1981; Vital status: Dead; Days to death: 1,120 days (3.1 years); Year of death: 2020; Country of birth: Poland.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 36.3 years (13,258 days); Year of diagnosis: 2017; Days to last known disease status: 1,120 days (3.1 years); Days to last follow up: 24 days.

Follow-up (1 entry)
- Days to follow up: 24 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 65 kg; Height: 171 cm; BMI: 22.23.

Biospecimens (3 samples)
- Sample C3N-00660-50: Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3N-00660-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Time between excision and freezing: 198 minutes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample C3N-00660-57: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 198 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
